Gene-level copy-number profile of tumor specimen ALCH-B2S8-TTP1-A from ALCHEMIST case ALCH-B2S8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.0 years (24,458 days).
Specimen ALCH-B2S8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba4a3278-68da-46e3-8546-9a4b4d9259bf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2S8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/5989f864-5e70-4a5b-8c2f-548b77fa60e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 11,373; copy number 2: 46,129; copy number 3: 1,315; copy number 4: 16; copy number 5: 9; copy number 12: 1; copy number 17: 1; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:9,143,166–9,146,106, 1 gene: AC093904.1.
- chr2:28,308,161–28,308,570, 1 gene (within-gene range 0–2): RPL23AP34.
- chr2:85,751,344–85,791,383, 2 genes: ATOH8, MIR6071.
- chr2:218,398,256–218,405,941, 3 genes (within-gene range 0–1): CTDSP1, AC021016.2, MIR26B.
- chr2:231,713,314–231,713,398, 1 gene: MIR1244-1.
- chr3:138,777,832–138,826,329, 3 genes (within-gene range 0–2): GAPDHP39, RPL23AP40, EEF1A1P25.
- chr4:1,100,016–1,101,558, 1 gene (within-gene range 0–1): AC092535.3.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr11:64,035,970–64,103,653, 2 genes (within-gene range 0–1): AP000721.2, AP006333.2.
- chr15:25,191,416–25,199,529, 5 genes (within-gene range 0–2): SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16.
- chr15:25,209,918–25,211,877, 2 genes (within-gene range 0–2): SNORD115-22, SNORD115-23.
- chr15:25,220,497–25,250,940, 18 genes (within-gene range 0–2): SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:64,701,248–64,825,668, 4 genes (within-gene range 0–2): AC100830.1, RBPMS2, MIR1272, PIF1.
- chr16:8,852,942–8,869,012, 1 gene (within-gene range 0–1): CARHSP1.
- chr16:8,869,251–8,870,032, 1 gene: AC022167.4.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–1): RNU6-1191P.
- chr17:29,071,122–29,180,398, 3 genes (within-gene range 0–2): MYO18A, TIAF1, AC024619.3.
- chr20:31,475,288–31,487,574, 2 genes (within-gene range 0–2): REM1, LINC00028.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr20:32,564,992–32,608,893, 2 genes (within-gene range 0–3): NOL4L-DT, AL133343.1.
- chr22:41,244,779–41,286,187, 2 genes: RANGAP1, MIR6889.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr4:1,166,932–1,208,962, 1 gene, copy number 5 (within-gene range 3–5): SPON2.
- chr7:102,681,836–102,690,469, 1 gene, copy number 12: RASA4DP.
- chr11:1,074,875–1,262,172, 5 genes, copy number 5: MUC2, MUC5AC, MUC5B, MUC5B-AS1, MIR6744.
- chr14:105,597,691–105,626,066, 2 genes, copy number 17–31 (within-gene range 3–31): IGHE, IGHG4.
- chr14:105,647,924–105,649,057, 1 gene, copy number 5: COPDA1.
- chr19:1,107,637–1,174,268, 1 gene, copy number 5: SBNO2.

Autosomal genes at a single copy (total copy number 1): 8,519. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
